Somatic mutation profile of tumor specimen TCGA-CQ-A4C6-01A (aliquot TCGA-CQ-A4C6-01A-11D-A25D-08) from TCGA case TCGA-CQ-A4C6, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 63.5 years (23,205 days).
Specimen TCGA-CQ-A4C6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9eaad68c-d530-40da-aceb-397908d3be1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-A4C6-10A (Blood Derived Normal), aliquot TCGA-CQ-A4C6-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d77112da-cafc-4303-82ab-8f2b976c599b

The open-access MAF lists 110 somatic variants for this specimen: 88 protein-altering or splice-affecting, 17 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 17, Nonsense Mutation 6, Splice Site 4, Intron 3, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | hotspot (GDC flag); catalogued as rs121913384, CM034218, CM095540, COSV58683071, COSV58683670; ClinVar: likely pathogenic; called by muse, varscan2
- NOTCH1 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 40/106 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53027071; called by muse, mutect2, varscan2
- PIK3CA | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 23/106 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 36/68 reads (53%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.1478G>T p.R493L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV101315794, COSV67984947; called by muse, varscan2
- AKAP6 | c.6937C>T p.R2313* | Nonsense Mutation (SNP) | VAF 37/119 reads (31%) | catalogued as rs777113901, COSV55216486; called by muse, mutect2, varscan2
- AMZ2 | c.1-1G>C p.X1_splice | Splice Site (SNP) | VAF 43/103 reads (42%) | catalogued as COSV100703146; called by muse, mutect2, varscan2
- ANKLE2 | c.1952T>C p.I651T | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV100514072; called by muse, mutect2, varscan2
- ARHGEF2 | c.1354C>T p.R452W (on ENST00000361247 / NM_001162383.2; = p.R424W on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1428651206, COSV100560477; called by muse, mutect2, varscan2
- ATG9A | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as rs761159469, COSV60134459; called by muse, mutect2, varscan2
- ATP8B2 | c.298C>G p.L100V (on ENST00000672630; = p.L67V on NM_001005855.2) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100527912; called by muse, mutect2, varscan2
- BPIFA2 | c.386T>A p.V129D | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99487857; called by muse, mutect2, varscan2
- C5orf15 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); catalogued as COSV99198317; called by muse, mutect2, varscan2
- CCDC142 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99282120; called by muse, mutect2, varscan2
- CCNG2 | c.1-1G>C p.X1_splice | Splice Site (SNP) | VAF 13/100 reads (13%) | catalogued as COSV100313215; called by muse, mutect2, varscan2
- CD101 | c.2707G>A p.D903N | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99869459; called by muse, mutect2, varscan2
- CEP135 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs765091582, COSV99954351; called by muse, mutect2, varscan2
- CFTR | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50075296, COSV99135131, COSV99135516; called by muse, mutect2, varscan2
- CLCN6 | c.1058G>A p.C353Y | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.636); catalogued as rs745893586, COSV100411854, COSV56742154, COSV56743438; called by muse, mutect2, varscan2
- CNBD2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100839080; called by muse, mutect2, varscan2
- CNGA1 | c.1163T>A p.I388N | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774292169, COSV100652211; called by muse, mutect2, varscan2
- COL22A1 | c.3865C>T p.P1289S | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.711); catalogued as COSV57340278, COSV57347063; called by muse, mutect2, varscan2
- COX7B2 | c.58C>G p.Q20E | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100260500; called by muse, mutect2, varscan2
- DPY19L1 | c.753C>G p.F251L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100204640, COSV60582436; called by muse, mutect2, varscan2
- DSP | c.2341G>C p.E781Q | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV101131246; called by muse, mutect2, varscan2
- DUSP7 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as COSV99623465; called by muse, mutect2, varscan2
- EIF3H | c.561G>C p.L187F | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV52671872; called by muse, mutect2, varscan2
- EN2 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1237336091, COSV52083942; called by muse, mutect2, varscan2
- FDPS | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as COSV99429715; called by muse, mutect2, varscan2
- FER1L5 | c.6081C>G p.I2027M (on ENST00000623019; = p.I1991M on NM_001293083.2) | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99383148; called by muse, mutect2, varscan2
- FLNB | c.3931G>A p.V1311M | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.663); catalogued as rs548108800, COSV99912835; called by muse, mutect2, varscan2
- FOS | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100338474; called by muse, mutect2, varscan2
- FOXI1 | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100089276; called by muse, mutect2, varscan2
- FRS3 | c.1375G>C p.D459H | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99442786; called by muse, mutect2, varscan2
- FRS3 | c.1207G>C p.D403H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99442790; called by muse, mutect2, varscan2
- GRID1 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs752715356, COSV100022404, COSV60016469, COSV60056647; called by muse, mutect2, varscan2
- GZMA | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs776260529, COSV57113676; called by muse, mutect2, varscan2
- HLA-C | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs281860364, COSV66113918; called by muse, mutect2, varscan2
- IMPG1 | c.367T>C p.Y123H | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV100886324; called by muse, mutect2, varscan2
- JMJD1C | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101232350; called by muse, mutect2
- KAT14 | c.955G>C p.D319H | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100890067; called by muse, mutect2, varscan2
- KCNC3 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338146006, COSV100979144; called by muse, mutect2, varscan2
- KDM4B | c.1907-1G>T p.X636_splice | Splice Site (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99346253; called by muse, mutect2, varscan2
- KIAA1755 | c.3112C>T p.R1038W | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs147257825, COSV99641678; called by muse, varscan2
- LRRN2 | c.1109C>G p.P370R | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100912819; called by muse, mutect2, varscan2
- LYST | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); catalogued as COSV101089135; called by muse, mutect2, varscan2
- MACF1 | c.18740G>C p.R6247T (on ENST00000372915; = p.R4292T on NM_012090.5) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as rs1456011440, COSV99243648; called by muse, mutect2, varscan2
- MAGI1 | c.2365C>A p.P789T | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770193154, COSV58322664; called by muse, mutect2, varscan2
- MAP3K4 | c.1013C>G p.S338* | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | catalogued as COSV100815287, COSV100815564; called by muse, mutect2, varscan2
- MC5R | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs1423428735, COSV61254131; called by muse, mutect2, varscan2
- MRPS15 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.276); catalogued as rs887384027, COSV58963103; called by muse, mutect2
- MTIF3 | c.423G>C p.Q141H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV101137473; called by muse, mutect2
- NR1I2 | c.152A>G p.Y51C | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100561542; called by muse, mutect2, varscan2
- PCDH1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs773816282, COSV54612927; called by muse, mutect2, varscan2
- PIGR | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.466); catalogued as COSV100732498; called by muse, mutect2, varscan2
- PKP2 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 61/299 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs765241754, COSV99297609; called by muse, mutect2, varscan2
- PLAA | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV101263512; called by muse, mutect2, varscan2
- PLAG1 | c.1082T>G p.M361R | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV100387847; called by muse, mutect2, varscan2
- PLVAP | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV99391606; called by muse, mutect2, varscan2
- PLXNB3 | c.2264C>T p.S755F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV100737333; called by muse, mutect2, varscan2
- PNLIP | c.1375C>A p.L459M | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100981610; called by muse, mutect2, varscan2
- POLR2B | c.1049A>G p.H350R | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100108025; called by muse, mutect2, varscan2
- PPP1R12B | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as COSV100407059; called by muse, mutect2, varscan2
- PSKH2 | c.135G>T p.R45S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs754441107, COSV52609583, COSV99405125; called by muse, mutect2, varscan2
- PTPN14 | c.2610G>C p.L870F | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100872496; called by muse, mutect2, varscan2
- R3HDM1 | c.2485G>A p.G829R | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1053999323, COSV51527064; called by muse, mutect2, varscan2
- RBM47 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV55934552, COSV99920586; called by muse, mutect2, varscan2
- RELN | c.5782C>A p.Q1928K | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100633449; called by muse, mutect2, varscan2
- RPF2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100923271; called by muse, mutect2, varscan2
- RYR2 | c.13006G>C p.D4336H | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100769680, COSV63663992; called by muse, mutect2, varscan2
- SCN3A | c.2233G>T p.A745S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV99326651; called by muse, mutect2
- SLC25A3 | c.664C>T p.P222S (on ENST00000228318 / NM_005888.3; = p.P221S on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99499171; called by muse, mutect2, varscan2
- SMG7 | c.3044C>G p.S1015C | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100750224, COSV61630462; called by muse, mutect2, varscan2
- SNUPN | c.476G>A p.G159D | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100419353; called by muse, varscan2
- SNUPN | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV100419356; called by muse, varscan2
- SORCS3 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs868423005, COSV63803356; called by muse, mutect2, varscan2
- SPG11 | c.6891G>C p.L2297F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99968475; called by muse, mutect2, varscan2
- SYNC | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 51/331 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as COSV100995279; called by muse, mutect2, varscan2
- SYNPO2L | c.2910G>C p.W970C (on ENST00000394810 / NM_001114133.3; = p.W746C on NM_024875.5) | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100831844; called by muse, mutect2, varscan2
- TRIP12 | c.1912-1G>C p.X638_splice | Splice Site (SNP) | VAF 5/42 reads (12%) | catalogued as COSV52260950, COSV99389981; called by muse, mutect2, varscan2
- TUT4 | c.4634C>T p.T1545M | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as rs746036876, COSV99932198; called by muse, mutect2, varscan2
- USP34 | c.10273G>A p.E3425K | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.025); catalogued as COSV100816002; called by muse, mutect2, varscan2
- VPS13B | c.8345C>T p.T2782M | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1297641779, COSV100661764; called by muse, mutect2, varscan2
- XKR3 | c.1074G>C p.M358I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV58884706; called by muse, mutect2, varscan2
- ZBTB26 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV101021064; called by muse, mutect2, varscan2
- ZNF792 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs757736763, COSV101289697; called by muse, mutect2, varscan2
- ZNF804A | c.1276G>T p.V426L | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV56456895, COSV56462599; called by muse, mutect2, varscan2
- UQCRHL | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- AP3D1 | c.1344G>A p.V448= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs774047537, COSV100642627; called by muse, mutect2, varscan2
- FNDC3B | c.831G>A p.S277= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs115364239; called by muse, mutect2, varscan2
- GK2 | c.1578C>T p.I526= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV100725929; called by muse, mutect2, varscan2
- GLIS3 | c.1914G>A p.Q638= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV100173824, COSV60923413; called by muse, mutect2, varscan2
- KCNG4 | c.1038C>T p.Y346= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs756227613, COSV100377029, COSV57582769; called by muse, mutect2, varscan2
- KIDINS220 | c.1353C>T p.L451= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV99875533; called by muse, mutect2, varscan2
- MAP4K1 | c.81G>A p.T27= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as rs776455319, COSV50264065; called by muse, mutect2, varscan2
- MYF5 | c.90C>T p.D30= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs750010723, COSV57356029; called by muse, mutect2, varscan2
- MYH9 | c.4473G>A p.Q1491= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99338608; called by muse, mutect2, varscan2
- NKAP | c.588G>A p.R196= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV101004214; called by muse, mutect2
- NWD1 | c.744C>T p.R248= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs377186225; called by muse, mutect2, varscan2
- PCDHB5 | c.1896C>T p.R632= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV50654939; called by muse, mutect2, varscan2
- PFKFB3 | c.603C>G p.L201= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV100431976; called by muse, mutect2, varscan2
- PLVAP | c.996G>A p.R332= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99391610; called by muse, mutect2, varscan2
- RTP4 | c.690C>A p.V230= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV52018912, COSV99372285; called by muse, mutect2, varscan2
- SLC35C1 | c.93G>A p.E31= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV100029378; called by muse, mutect2, varscan2
- UGT3A1 | c.78G>A p.L26= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV99954651; called by muse, mutect2, varscan2
- COL5A1 | c.654+7312G>C | Intron (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100879812; called by muse, mutect2
- NDE1 | c.*77C>T | 3'UTR (SNP) | VAF 8/74 reads (11%) | catalogued as rs1409716346, COSV100258667; called by muse, mutect2, varscan2
- R3HDM1 | c.2047+4024C>A | Intron (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99926113; called by muse, varscan2
- TROAP | c.337+132C>G | Intron (SNP) | VAF 10/75 reads (13%) | catalogued as COSV99226805; called by muse, mutect2, varscan2
- ZNF322P1 | n.1117C>T | RNA (SNP) | VAF 140/366 reads (38%) | catalogued as rs778672782; called by muse, mutect2, varscan2
